Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A7M6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A7M6-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Copied To

Report Patient	Name.
Demographics (for verification purposes)	Date of Birth
	Sex

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
Segment 7 of liver

Clinical Information
Chronic hepatitis C infection post blood transfusion ? causing hepatocellular Ca

Diagnosis

Liver, Segment 7, Resection:

- Hepatocellular carcinoma, Grade III.
- Well clear from resection margins.
- Background of portal and focal lobular chronic inflammation
- consistent with grade II, stage II HCV chronic hepatitis.

Reported by:

Electronically signed by:
Verified:

Synoptic Report

A: Liver, Resection, Macroscopic

Specimen:

Liver

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 2.5 cm

*Additional dimensions: 2.5 x 2.3 cm

TUMOR FOCALITY:

ICD-O-3
Carcinoma, Hepatocellular NOS
8170/3
Site Liver C22.0
MD 9/25/13

[page 2 of 2]
Solitary (specify location): Segment 7

A: Liver, Resection, Microscopic
HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GIII: Poorly differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 7 mm

Specify margin: parenchymal

Bile duct margin cannot be assessed

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Hepatitis (specify type): Hep C

Gross Description

Received is a single specimen container. The requisition and specimen container are labelled with the patient's name, The cassette and are labelled with the Surgical Number

The specimen is received fresh and is subsequently placed into formalin and labeled as segment 7 of liver. The specimen consists of a 24.7 g portion of liver, disc shaped, measuring 6.5 x 6 cm with a maximum thickness of 3 cm. The capsular surface has a plaque-like bulge approximately 2.5 cm in diameter, which on further sectioning, reveals a rounded pale brown tumorous nodule. This has a somewhat lobulated architecture and measures 2.3 x 2.5 x 2.5 cm. The resection surface of the tissue is painted blue. The tumor lies grossly within 0.7 cm of a resection surface. Representative sections including the resection are submitted in 10 cassettes.

Microscopic Description

Microscopy shows a multinodular hepatocellular carcinoma, the tumor growing in confluent compact sheets as well areas of trabeculae. They are polygonal shaped, show moderate nuclear pleomorphism and in the more solid areas show prominent mitotic activity. There is also a mild inflammatory with neutrophils and focal lymphocytes extending into the carcinoma. There is a central area of degeneration, but no evidence of direct vascular invasion can be identified. Surrounding hepatic parenchyma shows mild to moderate chronic inflammation in portal tracts with focal degeneration of the interface (piecemeal necrosis). There is mild expansion of portal tracts and focal portal portal fibrous septa in a pattern consistent with Stage II fibrosis. Focal lobular lymphocytic inflammation is consistent with Grade II inflammation.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file bfd6f5ea-4103-46ca-b807-ba1b6cfa6130 (TCGA-G3-A7M6.BE9902BC-2818-4A37-AF40-768208EA15B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).